Somatic mutation profile of tumor specimen TARGET-10-PARCBK-09A (aliquot TARGET-10-PARCBK-09A-01D) from TARGET case TARGET-10-PARCBK, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 16.5 years (6,030 days).
Specimen TARGET-10-PARCBK-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 990af0a9-9739-49c7-980c-597a788edcf6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARCBK-10A (Blood Derived Normal), aliquot TARGET-10-PARCBK-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/009cd332-fda7-4dc2-861a-a16c6fdf9a07

The open-access MAF lists 19 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 3, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP002512.3 | c.365G>T p.C122F | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.3); catalogued as COSV54406732; called by muse, mutect2
- ARID1B | c.2108C>T p.A703V | Missense Mutation (SNP) | VAF 49/98 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); catalogued as rs774701560, COSV51653006; called by muse, mutect2, varscan2
- CRYBB1 | c.193G>T p.E65* | Nonsense Mutation (SNP) | VAF 9/165 reads (5%) | catalogued as COSV53232441; called by muse, mutect2
- OR10C1 | c.766G>A p.A256T (on ENST00000622521; = p.A254T on NM_013941.3) | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as rs374582900, COSV65824422; called by muse, mutect2, varscan2
- TOGARAM2 | c.1249G>A p.G417S | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs868850533, COSV65422501; called by muse, mutect2, varscan2
- U2AF2 | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs759632598; called by muse, varscan2
- ZAN | c.3782C>T p.T1261M | Missense Mutation (SNP) | VAF 90/219 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771443188; called by muse, mutect2, varscan2
- ZFHX4 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50645080; called by muse, mutect2, varscan2
- AMIGO2 | c.469G>T p.D157Y | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- ATP1A1 | c.2713C>A p.Q905K | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- MMS19 | c.1513G>T p.A505S | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); called by muse, mutect2
- NLRP2 | c.522C>A p.S174R | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.584); called by muse, mutect2
- NT5C3A | c.964G>A p.V322I (on ENST00000610140 / NM_001374335.1; = p.V288I on NM_016489.13) | Missense Mutation (SNP) | VAF 27/201 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2
- PTPRF | c.1465C>A p.L489I | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.93); called by muse, mutect2
- RESP18 | c.173T>A p.L58H | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ANK2 | c.450G>T p.L150= | Silent (SNP) | VAF 51/108 reads (47%) | called by muse, mutect2, varscan2
- C3orf20 | c.1414C>T p.L472= | Silent (SNP) | VAF 11/24 reads (46%) | called by muse, mutect2, varscan2
- ZNF782 | c.636G>T p.G212= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as COSV56651882; called by muse, mutect2
- PLEKHA6 | c.1525-978_1525-977del | Intron (DEL) | VAF 8/43 reads (19%) | called by pindel, varscan2
